Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6EV, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6EV-01A (Primary Tumor).

c6CF ICD-O-3
Stomach Adenocarcinoma, NOS 8140/3
path
Adenocarcinoma, tubular + villous
(8211/3) (8262/3)
code to highest 8262/3
Site c6CF Gastric antrum c16.3
path Pylorus c16.4

Department of Cancer Pathology

Op 6/25/13

Patient: XXX

Age:

Gender: F

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer.**

Date of admission:

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Poorly differentiated stomach adenocarcinoma
Metastases to 3/17 adjacent lymph nodes.
Vessels invaded.
(G3; pT2; pN1; R0). (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 18.3 x 13.2cm with the omentum sized 32 x 25cm.
Tumour sized 5.6 x 4.1 x 0.8cm in the pyloric region on the back wall.
Distance from the proximal end: 9.6cm, from distal end: 1.2cm.

Microscopic description:

Poorly differentiated tubular and villous adenocarcinoma (mixed type acc. to Lauren class). Invasion of the submucosa and shallow invasion of the gastric muscular membrane.
Incision lines free of neoplastic lesions.
Off tumour: chronic inflammation (+) with no signs of activity (-) and foci of complete intestinal metaplasia (+) (prep.M)..
LYMPH NODES:
1,2- (cardia) (N): Cancer involvement (2 nodes)
3 - (lesser curvature) (P,R): Cancer involvement (7 nodes)
4 - (greater curvature) (S,T);
Metastases to 3/6 nodes.
Signs of perilymphatic invasion.
6 - (peripyloric) (U): Cancer involvement (2 nodes)

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Histo Discrepancy		✓
Case is (circled):	CONFIRMED	DISQUALIFIED
Reviewed Initials	KML	5/17/13

Source: NCI Genomic Data Commons file 0415c79b-73df-4e7f-990e-c21851c8e848 (TCGA-D7-A6EV.2FFC6975-9EB5-438B-9799-8849D28D6A5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).